Somatic mutation profile of tumor specimen 0DJ6KM from CCDI case PBBWNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 19.2 years (7,022 days).
Specimen 0DJ6KM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3580e89-9574-4602-bfee-a7508f4b2811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/691f92ca-62e8-46cd-b2ef-b8be5af8e40a

The open-access MAF lists 134 somatic variants for this specimen: 89 protein-altering or splice-affecting, 26 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 26, Nonsense Mutation 9, Intron 9, 5'UTR 6, 3'UTR 3, Splice Region 2, 5'Flank 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 246/1311 reads (19%) | catalogued as rs55861249, CM960096, COSV53734495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 117/1070 reads (11%) | catalogued as COSV57866483; called by muse, mutect2, varscan2
- AR | c.2012A>G p.Q671R | Missense Mutation (SNP) | VAF 74/776 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101017223, COSV65956987, COSV65961677; called by muse, mutect2
- C1QC | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 76/749 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV65889986; called by muse, mutect2, varscan2
- C2CD5 | c.-29-3C>T | Splice Region (SNP) | VAF 65/864 reads (8%) | catalogued as rs1217514634; called by muse, mutect2
- C6orf118 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 63/988 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV57813208; called by muse, mutect2
- CARMIL3 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 86/926 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs375461974; called by muse, mutect2
- CCDC39 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 172/1884 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1338737312; called by muse, mutect2
- CDYL | c.622G>A p.A208T (on ENST00000328908 / NM_001368125.1; = p.A154T on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/1515 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs748320096; called by muse, mutect2
- CLEC16A | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1332004175; called by muse, mutect2
- CNTLN | c.3412C>T p.R1138* | Nonsense Mutation (SNP) | VAF 173/1938 reads (9%) | catalogued as rs754459158; called by muse, mutect2
- CNTN4 | c.1981G>A p.V661M | Missense Mutation (SNP) | VAF 124/1424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138936543; called by muse, mutect2
- COL27A1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs144241003; called by muse, mutect2
- COLGALT2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 88/1371 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs754514520, COSV62299859; called by muse, mutect2
- CYYR1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 133/1272 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as COSV100177259, COSV100177546; called by muse, mutect2, varscan2
- EPB41L3 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 102/959 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs375861416, COSV59471850; called by muse, mutect2, varscan2
- ETV6 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 177/2417 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs764237239; called by muse, mutect2
- FERD3L | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 110/1168 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV51761976, COSV51764624; called by muse, mutect2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 78/851 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 82/1274 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by muse, mutect2
- GJD4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 88/1146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201912261; called by muse, mutect2
- GK2 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 116/1304 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV62627743; called by muse, mutect2
- LIG3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 102/1918 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs142734285; called by muse, mutect2
- MAP4K2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 59/736 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as rs140728936; called by muse, mutect2
- MGAM2 | c.3346C>T p.P1116S | Missense Mutation (SNP) | VAF 53/1618 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs1288756339; called by muse, mutect2
- NEK5 | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 112/1330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100839279; called by muse, mutect2
- OR2L8 | c.8A>T p.N3I | Missense Mutation (SNP) | VAF 218/1338 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV61728461; called by muse, mutect2, varscan2
- PHKA2 | c.3336+5G>A | Splice Region (SNP) | VAF 81/769 reads (11%) | catalogued as rs1297577445; called by muse, mutect2, varscan2
- PLD5 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 86/1074 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.899); catalogued as rs755085764; called by muse, mutect2
- SAP18 | c.99C>G p.F33L (on ENST00000607003; = p.F52L on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/1582 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101229418; called by muse, mutect2
- SLC45A1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 297/779 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs146331013; called by muse, mutect2, varscan2
- SLITRK6 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 149/1819 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs762161848, COSV68390792; called by muse, mutect2
- SPANXN1 | c.144T>G p.Y48* | Nonsense Mutation (SNP) | VAF 68/1696 reads (4%) | catalogued as COSV65122023; called by muse, mutect2
- UBR5 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 118/1272 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.025); catalogued as rs1427637896, COSV55284652; called by muse, mutect2
- VAX1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs1390036718; called by muse, mutect2, varscan2
- ZNF536 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 58/754 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1056766328, COSV62825312, COSV62831756; called by muse, mutect2
- ZNF670 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 179/2158 reads (8%) | catalogued as rs866450813, COSV63608331, COSV63608354; called by muse, mutect2
- ZNF677 | c.1165A>C p.S389R | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.717); catalogued as COSV100448184; called by muse, mutect2
- ZNF718 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 28/980 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374273521; called by muse, mutect2
- ZNF724 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 80/1054 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs1278473618; called by muse, mutect2
- ALDH8A1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 84/886 reads (9%) | called by muse, mutect2
- ATP4A | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 103/517 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN2L | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2
- BAHCC1 | c.4211G>T p.R1404M | Missense Mutation (SNP) | VAF 52/798 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- CHL1 | c.1031C>G p.T344S (on ENST00000397491 / NM_001253387.1; = p.T360S on NM_006614.4) | Missense Mutation (SNP) | VAF 173/1734 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CRB2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 27/951 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); called by muse, mutect2
- CRHR2 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); called by muse, mutect2
- DSCAM | c.2904G>T p.K968N | Missense Mutation (SNP) | VAF 144/1496 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- EYS | c.3183T>G p.N1061K | Missense Mutation (SNP) | VAF 53/1650 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- F13A1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 46/1348 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- FCHO2 | c.267T>A p.D89E | Missense Mutation (SNP) | VAF 117/1576 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GPX4 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 33/722 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- HBS1L | c.1978A>T p.K660* | Nonsense Mutation (SNP) | VAF 151/1758 reads (9%) | called by muse, mutect2
- HS3ST2 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 102/1190 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ITGAE | c.3156G>A p.W1052* | Nonsense Mutation (SNP) | VAF 128/844 reads (15%) | called by muse, varscan2
- KAT2B | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 96/1314 reads (7%) | called by muse, mutect2
- KCNAB1 | c.304T>C p.S102P (on ENST00000490337 / NM_172160.3; = p.S91P on NM_003471.3) | Missense Mutation (SNP) | VAF 92/1216 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIF4A | c.2024_2027del p.L675* | Frame Shift Del (DEL) | VAF 83/876 reads (9%) | called by mutect2, pindel
- LTBP1 | c.2702A>G p.Y901C (on ENST00000404816 / NM_206943.4; = p.Y575C on NM_000627.4) | Missense Mutation (SNP) | VAF 94/1224 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); called by muse, mutect2
- MALRD1 | c.4854A>C p.K1618N | Missense Mutation (SNP) | VAF 35/925 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.109); called by muse, mutect2
- MFSD8 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 108/1154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MYF6 | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 118/1526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH1 | c.1996T>G p.L666V | Missense Mutation (SNP) | VAF 66/1650 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- MYO10 | c.3199T>C p.S1067P | Missense Mutation (SNP) | VAF 130/612 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NFE2 | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 61/762 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2
- NOL10 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 146/1649 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- NR4A3 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 52/673 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- OR8B3 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 164/2059 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHC1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 70/1238 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- POLR2B | c.1967T>G p.L656R | Missense Mutation (SNP) | VAF 61/663 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POTEG | c.966C>G p.S322R | Missense Mutation (SNP) | VAF 60/1348 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.609); called by muse, mutect2
- PPP1R3F | c.1858T>C p.W620R | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- PXDN | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 72/1088 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- RINL | c.748C>G p.P250A (on ENST00000591812 / NM_001195833.2; = p.P136A on NM_198445.4) | Missense Mutation (SNP) | VAF 81/600 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RYR1 | c.8285C>T p.T2762I | Missense Mutation (SNP) | VAF 67/940 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2
- SHH | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.3); called by muse, varscan2
- SLC5A12 | c.951+1G>T p.X317_splice | Splice Site (SNP) | VAF 94/1056 reads (9%) | called by muse, mutect2
- SLC8A3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 56/823 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TERF2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2
- TNC | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 95/979 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNFRSF10A | c.168_182del p.T57_Q61del | In Frame Del (DEL) | VAF 79/364 reads (22%) | called by mutect2, pindel, varscan2
- TNFSF11 | c.607A>G p.N203D | Missense Mutation (SNP) | VAF 158/1716 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2
- TRIM64B | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 147/3577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- UGP2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 88/1362 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- UNC79 | c.2936T>G p.L979R (on ENST00000393151 / NM_001346218.2; = p.L802R on NM_020818.5) | Missense Mutation (SNP) | VAF 130/931 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USH1C | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZKSCAN3 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 114/1385 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- ZMYM6 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 78/1092 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF345 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2
- APOB | c.11952C>T p.T3984= | Silent (SNP) | VAF 163/1970 reads (8%) | catalogued as rs1447813723, COSV51941498; called by muse, mutect2
- ARHGAP35 | c.2637T>C p.D879= | Silent (SNP) | VAF 74/692 reads (11%) | catalogued as rs1385677983; called by muse, mutect2
- ASTN1 | c.2343C>T p.I781= | Silent (SNP) | VAF 37/1217 reads (3%) | catalogued as COSV99922022; called by muse, mutect2
- BIN3 | c.324C>T p.I108= | Silent (SNP) | VAF 57/978 reads (6%) | catalogued as rs751485461; called by muse, mutect2
- CELSR3 | c.570C>T p.N190= | Silent (SNP) | VAF 104/815 reads (13%) | catalogued as COSV50850305; called by muse, mutect2, varscan2
- DROSHA | c.2310G>A p.P770= | Silent (SNP) | VAF 266/1633 reads (16%) | catalogued as rs759781794; called by muse, mutect2, varscan2
- ELAPOR2 | c.2817C>T p.A939= (on ENST00000450689 / NM_001142749.3; = p.A772= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 142/2160 reads (7%) | catalogued as rs749403913, COSV51888439; called by muse, mutect2
- FGF23 | c.189C>T p.G63= | Silent (SNP) | VAF 90/1434 reads (6%) | catalogued as rs747478192, COSV52978548; called by muse, mutect2
- GLI2 | c.4305C>T p.H1435= (on ENST00000361492 / NM_001374353.1; = p.H1452= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/747 reads (5%) | catalogued as rs769362375; called by muse, mutect2
- GPR142 | c.294A>G p.Q98= | Silent (SNP) | VAF 96/1204 reads (8%) | called by muse, mutect2
- IRX4 | c.1236G>A p.T412= | Silent (SNP) | VAF 55/528 reads (10%) | called by muse, mutect2, varscan2
- JARID2 | c.2520G>A p.E840= | Silent (SNP) | VAF 53/1230 reads (4%) | called by muse, mutect2
- KIF15 | c.2145T>C p.I715= | Silent (SNP) | VAF 44/835 reads (5%) | called by muse, mutect2
- LRP1 | c.11784C>T p.S3928= | Silent (SNP) | VAF 91/1000 reads (9%) | called by muse, mutect2
- MCM7 | c.462T>C p.A154= | Silent (SNP) | VAF 98/1534 reads (6%) | called by muse, mutect2
- MYH13 | c.156C>T p.I52= | Silent (SNP) | VAF 58/1448 reads (4%) | catalogued as rs759213643; called by muse, mutect2
- NPB | c.366C>T p.C122= | Silent (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- OR6N2 | c.105C>T p.Y35= | Silent (SNP) | VAF 130/1169 reads (11%) | called by muse, mutect2, varscan2
- PGR | c.1311G>A p.A437= | Silent (SNP) | VAF 47/486 reads (10%) | catalogued as COSV99677349; called by muse, mutect2, varscan2
- PIK3AP1 | c.1434G>T p.R478= | Silent (SNP) | VAF 175/961 reads (18%) | called by muse, mutect2, varscan2
- QRSL1 | c.1011G>A p.S337= | Silent (SNP) | VAF 136/1248 reads (11%) | catalogued as rs143085016; called by muse, mutect2, varscan2
- RNF4 | c.360C>T p.G120= | Silent (SNP) | VAF 49/620 reads (8%) | catalogued as rs1289361999, COSV58642920; called by muse, mutect2
- SPAG16 | c.975T>C p.N325= | Silent (SNP) | VAF 47/1736 reads (3%) | called by muse, mutect2
- TKTL2 | c.1371G>A p.S457= | Silent (SNP) | VAF 80/911 reads (9%) | catalogued as rs775147166; called by muse, mutect2
- UNC79 | c.5166C>T p.D1722= (on ENST00000393151 / NM_001346218.2; = p.D1545= on NM_020818.5) | Silent (SNP) | VAF 56/1004 reads (6%) | catalogued as rs773882042, COSV56386758; called by muse, mutect2
- ZNF432 | c.1692A>G p.T564= | Silent (SNP) | VAF 40/1232 reads (3%) | called by muse, mutect2
- BHLHE22 | c.-29C>T | 5'UTR (SNP) | VAF 75/824 reads (9%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/375 reads (3%) | called by muse, mutect2
- CARD11 | c.*33G>A | 3'UTR (SNP) | VAF 49/523 reads (9%) | catalogued as rs372583811; called by muse, mutect2
- CNIH3 | c.*37G>A | 3'UTR (SNP) | VAF 93/1241 reads (7%) | called by muse, mutect2
- ERICH6 | chr3:150703944 C>G | 5'Flank (SNP) | VAF 17/162 reads (10%) | catalogued as rs746209362, COSV55801157; called by muse, mutect2
- FBLN1 | c.1698-11399G>A | Intron (SNP) | VAF 60/740 reads (8%) | catalogued as rs11551; called by muse, mutect2
- GABRB3 | c.-21G>A | 5'UTR (SNP) | VAF 47/315 reads (15%) | catalogued as COSV54660948; called by muse, mutect2, varscan2
- GPC2 | c.730-27G>A | Intron (SNP) | VAF 53/616 reads (9%) | called by muse, mutect2
- HTR2A | c.-345G>T | 5'UTR (SNP) | VAF 153/994 reads (15%) | called by muse, mutect2, varscan2
- KBTBD8 | c.-5G>A | 5'UTR (SNP) | VAF 98/1242 reads (8%) | catalogued as rs1403794959; called by muse, mutect2
- MGAT4A | c.-49C>T | 5'UTR (SNP) | VAF 34/358 reads (9%) | called by muse, mutect2
- MYBBP1A | c.3196-9C>T | Intron (SNP) | VAF 47/304 reads (15%) | called by muse, mutect2, varscan2
- NRG1 | c.502+30991C>T | Intron (SNP) | VAF 67/584 reads (11%) | catalogued as rs184949901; called by muse, mutect2, varscan2
- SEM1 | c.-13G>C | 5'UTR (SNP) | VAF 90/705 reads (13%) | catalogued as rs1264133862, COSV99949670; called by muse, mutect2, varscan2
- SERPINI2 | c.1052-47G>A | Intron (SNP) | VAF 736/1240 reads (59%) | catalogued as rs756841628; called by muse, varscan2
- SFI1 | c.266+74G>A | Intron (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- TTC17 | c.531+34_531+47delinsTTGCGTTCTTA | Intron (DEL) | VAF 3/33 reads (9%) | called by pindel, varscan2*
- XRCC4 | c.893+16C>A | Intron (SNP) | VAF 72/649 reads (11%) | catalogued as COSV99982805; called by muse, mutect2, varscan2
- ZFP30 | c.*98G>T | 3'UTR (SNP) | VAF 56/261 reads (21%) | catalogued as COSV100665928; called by muse, mutect2, varscan2
